Somatic mutation profile of tumor specimen ALCH-B37R-TTP1-A (aliquot ALCH-B37R-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B37R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.7 years (26,540 days).
Specimen ALCH-B37R-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1aa5727-be7e-41bf-9453-d403c6bb8f8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B37R-NB1-A (Blood Derived Normal), aliquot ALCH-B37R-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2db3b72f-8ad3-4e81-a87f-a59f95f3591a

The open-access MAF lists 164 somatic variants for this specimen: 118 protein-altering or splice-affecting, 28 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 28, Nonsense Mutation 14, Intron 6, RNA 5, Splice Site 3, 3'Flank 2, 5'UTR 2, 5'Flank 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 49/685 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AC011455.2 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 72/588 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV55498816; called by muse, mutect2, varscan2
- ADAMTS3 | c.2884A>G p.N962D | Missense Mutation (SNP) | VAF 40/813 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs1375942467; called by muse, mutect2
- AGBL4 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 44/642 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV65735270; called by muse, mutect2
- ANKMY1 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146962817; called by muse, mutect2, varscan2
- ARSF | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 32/576 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV63839216; called by muse, mutect2
- ART3 | c.843C>G p.N281K | Missense Mutation (SNP) | VAF 22/762 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV61913887; called by muse, mutect2
- CGNL1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 24/497 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1178562309; called by muse, mutect2
- CHRM1 | c.628C>A p.R210S | Missense Mutation (SNP) | VAF 20/543 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100186134; called by muse, mutect2
- CREB3L1 | c.754-1G>T p.X252_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | catalogued as COSV55832123; called by muse, mutect2
- CSMD3 | c.3976C>G p.Q1326E (on ENST00000297405 / NM_001363185.1; = p.Q1222E on NM_052900.3) | Missense Mutation (SNP) | VAF 26/918 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV52104687; called by muse, mutect2
- DCAF4L2 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs567814460, COSV100150690; called by muse, mutect2
- DZIP1L | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 28/698 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764030474; called by muse, mutect2
- EIF4G1 | c.3745A>G p.I1249V (on ENST00000346169 / NM_198241.3; = p.I1054V on NM_004953.5) | Missense Mutation (SNP) | VAF 44/574 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs912051185, COSV99048757; called by muse, mutect2
- EML4 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1448227946; called by muse, mutect2
- FRYL | c.8657C>A p.S2886Y | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV51965579; called by muse, mutect2
- H3-5 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV100461670; called by muse, mutect2
- ITIH2 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs199888149, COSV100623341; called by muse, mutect2
- KCNQ3 | c.2348C>A p.T783K | Missense Mutation (SNP) | VAF 25/392 reads (6%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.982); catalogued as COSV66475435; called by muse, mutect2
- KEAP1 | c.845A>C p.Q282P | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV50260998; called by muse, mutect2
- LILRB5 | c.1744C>T p.P582S (on ENST00000449561 / NM_001081442.3; = p.P581S on NM_006840.5) | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.379); catalogued as rs1319407371; called by muse, mutect2
- LRP1B | c.7269G>T p.W2423C | Missense Mutation (SNP) | VAF 36/914 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101257986; called by muse, mutect2
- MAP1B | c.1512G>C p.K504N | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99702630; called by muse, mutect2
- MDGA2 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1259665243, COSV100636435; called by muse, mutect2
- MTA1 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100231719; called by muse, mutect2
- MUC16 | c.6311G>C p.R2104T | Missense Mutation (SNP) | VAF 36/541 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV67446402; called by muse, mutect2
- OR6C75 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 30/1161 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.4); catalogued as COSV58552900; called by muse, mutect2
- PCDHA7 | c.1504C>A p.R502S | Missense Mutation (SNP) | VAF 56/602 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV65347593; called by muse, mutect2
- PCDHB14 | c.1013T>C p.M338T | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); catalogued as rs1554289193; called by muse, mutect2
- PLA2G4A | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 69/1296 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV66555253; called by muse, mutect2
- PPP1R13L | c.938A>C p.Y313S | Missense Mutation (SNP) | VAF 28/417 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV62909191; called by muse, mutect2
- PRDM9 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 60/1014 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV57005217, COSV57014577; called by muse, mutect2
- PRG4 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 75/1427 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.567); catalogued as COSV66626158; called by muse, mutect2
- PTCD1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 24/452 reads (5%) | catalogued as rs201306967; called by muse, mutect2
- PTPN5 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 20/318 reads (6%) | catalogued as rs371630924; called by muse, mutect2
- SCN10A | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 47/796 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756235256, COSV71860938; called by muse, mutect2
- TAF1L | c.5195C>T p.P1732L | Missense Mutation (SNP) | VAF 28/678 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV54259768, COSV54266508; called by muse, mutect2
- TBX22 | c.1552C>A p.H518N | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV64788028; called by muse, mutect2
- THSD7A | c.759C>G p.Y253* | Nonsense Mutation (SNP) | VAF 46/418 reads (11%) | catalogued as COSV70265563; called by muse, mutect2
- TMPRSS15 | c.1126C>G p.P376A | Missense Mutation (SNP) | VAF 42/711 reads (6%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.673); catalogued as rs200225629; called by muse, mutect2
- TSGA10IP | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs1181231403; called by muse, mutect2
- USH2A | c.2167+1G>T p.X723_splice | Splice Site (SNP) | VAF 40/998 reads (4%) | catalogued as COSV56349268; called by muse, mutect2
- ZC2HC1C | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 20/615 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as rs1319390772; called by muse, mutect2
- ZC3H12A | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 10/136 reads (7%) | catalogued as COSV66104191; called by muse, mutect2
- ZNF790 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV63211932; called by muse, mutect2
- ABCA12 | c.7064A>G p.Y2355C (on ENST00000272895 / NM_173076.3; = p.Y2037C on NM_015657.3) | Missense Mutation (SNP) | VAF 44/661 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGB | c.4244G>T p.G1415V | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ADHFE1 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 18/509 reads (4%) | called by muse, mutect2
- AGGF1 | c.800A>T p.K267I | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ATP10B | c.1098C>A p.Y366* | Nonsense Mutation (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- BANF2 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- C3orf85 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 32/724 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); called by muse, mutect2
- CD96 | c.1154C>T p.T385I (on ENST00000283285 / NM_198196.3; = p.T369I on NM_005816.5) | Missense Mutation (SNP) | VAF 24/862 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2
- CDK9 | c.393G>T p.Q131H | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2
- CEBPE | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.72); called by muse, mutect2
- CHD5 | c.5580C>A p.V1860= | Splice Region (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- CHST7 | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.095); called by muse, mutect2
- CLTCL1 | c.1801G>T p.G601* | Nonsense Mutation (SNP) | VAF 17/254 reads (7%) | called by muse, mutect2
- COL6A1 | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.925); called by muse, mutect2
- CR2 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 54/822 reads (7%) | called by muse, mutect2
- CREB3L1 | c.754A>C p.K252Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CSMD3 | c.9808G>T p.V3270F (on ENST00000297405 / NM_001363185.1; = p.V3101F on NM_052900.3) | Missense Mutation (SNP) | VAF 63/869 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- DHX29 | c.3616C>T p.Q1206* | Nonsense Mutation (SNP) | VAF 26/600 reads (4%) | called by muse, mutect2
- DHX29 | c.3112T>G p.L1038V | Missense Mutation (SNP) | VAF 48/637 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.268); called by muse, mutect2
- DYRK4 | c.412A>T p.K138* | Nonsense Mutation (SNP) | VAF 12/275 reads (4%) | called by muse, mutect2
- DYSF | c.3956A>G p.Y1319C | Missense Mutation (SNP) | VAF 62/684 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- FANCM | c.1051-1G>A p.X351_splice | Splice Site (SNP) | VAF 20/598 reads (3%) | called by muse, mutect2
- GCNT3 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); called by muse, mutect2
- GTF3C3 | c.1901A>T p.Y634F | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- INTS8 | c.1945A>G p.R649G | Missense Mutation (SNP) | VAF 29/362 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2
- KCNH5 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 30/519 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCTD8 | c.147C>A p.N49K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KHDRBS2 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LPIN1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 34/630 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.048); called by muse, mutect2
- MGAM2 | c.5117G>T p.W1706L | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTUS2 | c.2336C>A p.P779Q | Missense Mutation (SNP) | VAF 65/1026 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC12 | c.599C>A p.T200K (on ENST00000379442; = p.T57K on NM_001164462.1) | Missense Mutation (SNP) | VAF 38/666 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); called by muse, mutect2
- MYO18B | c.3636T>G p.S1212R | Missense Mutation (SNP) | VAF 28/782 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- NCKAP5 | c.3127A>G p.R1043G | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- NIN | c.3768C>G p.S1256R | Missense Mutation (SNP) | VAF 32/668 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); called by muse, mutect2
- NPAP1 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NPBWR2 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 50/507 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- OR14K1 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 42/812 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); called by muse, mutect2
- OR52H1 | c.70C>A p.Q24K (on ENST00000322653; = p.Q30K on NM_001005289.1) | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- OXR1 | c.616G>T p.E206* (on ENST00000442977 / NM_001198532.1; = p.E205* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 22/347 reads (6%) | called by muse, mutect2
- PASD1 | c.2101G>T p.G701C | Missense Mutation (SNP) | VAF 43/380 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PCDHGB3 | c.1516T>G p.S506A | Missense Mutation (SNP) | VAF 30/493 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- PCLO | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 23/845 reads (3%) | called by muse, mutect2
- PCNX4 | c.2794T>G p.L932V (on ENST00000406854 / NM_001330177.2; = p.L698V on NM_022495.5) | Missense Mutation (SNP) | VAF 38/560 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.122); called by muse, mutect2
- PDCL | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 30/588 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- PHLDB2 | c.2237A>T p.Q746L (on ENST00000393925 / NM_001134439.2; = p.Q703L on NM_145753.2) | Missense Mutation (SNP) | VAF 21/421 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- PIK3CG | c.988A>T p.T330S | Missense Mutation (SNP) | VAF 24/369 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2
- PITPNM3 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 31/633 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.133); called by muse, mutect2
- PKHD1 | c.6599A>T p.Q2200L | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- PKHD1 | c.5143C>A p.H1715N | Missense Mutation (SNP) | VAF 36/779 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- PLXND1 | c.2429A>T p.Q810L | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPFIA2 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.996); called by muse, mutect2
- PTK6 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PTPRO | c.2963A>T p.E988V (on ENST00000281171 / NM_030667.3; = p.E960V on NM_002848.4) | Missense Mutation (SNP) | VAF 30/1077 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2
- PTPRS | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); called by muse, mutect2
- RAD21L1 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.111); called by muse, mutect2
- RANBP2 | c.7183A>T p.M2395L | Missense Mutation (SNP) | VAF 101/1942 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.959); called by muse, mutect2
- RPS25 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2
- RYR3 | c.12322G>A p.D4108N (on ENST00000389232; = p.D4109N on NM_001036.6) | Missense Mutation (SNP) | VAF 41/611 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by muse, mutect2
- SCN9A | c.3650A>G p.E1217G (on ENST00000303354; = p.E1206G on NM_002977.3) | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- SLC2A5 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 24/382 reads (6%) | called by muse, mutect2
- SLCO4C1 | c.1555G>C p.G519R | Missense Mutation (SNP) | VAF 47/740 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2
- SMARCA4 | c.3087A>T p.K1029N | Missense Mutation (SNP) | VAF 60/684 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2
- SPEF2 | c.1730G>C p.R577T | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- TNN | c.2785G>T p.V929F | Missense Mutation (SNP) | VAF 30/652 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2
- TRPV1 | c.1883A>T p.Y628F | Missense Mutation (SNP) | VAF 36/591 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- TTN | c.54106C>G p.P18036A (on ENST00000591111; = p.P10612A on NM_003319.4) | Missense Mutation (SNP) | VAF 42/688 reads (6%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- TXNDC16 | c.740T>A p.M247K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- USH2A | c.3772G>T p.E1258* | Nonsense Mutation (SNP) | VAF 25/436 reads (6%) | called by muse, mutect2
- VWA3B | c.2119T>C p.W707R | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2
- ZNF33B | c.697G>T p.V233L | Missense Mutation (SNP) | VAF 27/395 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ZNF527 | c.1420A>C p.K474Q | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.063); called by muse, mutect2
- ZNF574 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.045); called by muse, mutect2
- AL445989.1 | c.327C>A p.G109= | Silent (SNP) | VAF 117/1518 reads (8%) | called by muse, varscan2
- AMH | c.1089G>A p.L363= | Silent (SNP) | VAF 10/96 reads (10%) | called by mutect2, varscan2
- ANKFY1 | c.1429C>T p.L477= | Silent (SNP) | VAF 24/645 reads (4%) | catalogued as rs1199111111; called by muse, mutect2
- ANKFY1 | c.1428C>T p.F476= | Silent (SNP) | VAF 24/648 reads (4%) | called by muse, mutect2
- AP2M1 | c.810A>T p.G270= | Silent (SNP) | VAF 32/498 reads (6%) | called by muse, mutect2
- ARHGEF25 | c.516G>A p.E172= | Silent (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- DYNC2H1 | c.9342A>G p.A3114= | Silent (SNP) | VAF 26/578 reads (4%) | called by muse, mutect2
- EP400 | c.531G>C p.V177= | Silent (SNP) | VAF 30/710 reads (4%) | called by muse, mutect2
- ERC1 | c.2484A>G p.L828= (on ENST00000360905 / NM_178040.4; = p.L800= on NM_178039.4) | Silent (SNP) | VAF 14/345 reads (4%) | catalogued as rs1226786757; called by muse, mutect2
- FOXN2 | c.1104A>C p.A368= | Silent (SNP) | VAF 46/776 reads (6%) | catalogued as rs953114067; called by muse, mutect2
- GCN1 | c.6942G>T p.L2314= | Silent (SNP) | VAF 30/545 reads (6%) | catalogued as rs755254618, COSV100325368; called by muse, mutect2
- KATNIP | c.3897C>T p.I1299= | Silent (SNP) | VAF 26/434 reads (6%) | catalogued as COSV99851512; called by muse, mutect2
- KNDC1 | c.2358C>T p.P786= | Silent (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- LSM2 | c.189G>T p.R63= | Silent (SNP) | VAF 30/669 reads (4%) | called by muse, mutect2
- MACROD1 | c.573C>T p.A191= | Silent (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- MYO3B | c.3877A>C p.R1293= | Silent (SNP) | VAF 42/699 reads (6%) | called by muse, mutect2
- OR10A3 | c.916C>A p.R306= | Silent (SNP) | VAF 8/240 reads (3%) | catalogued as COSV62460504; called by muse, mutect2
- PAK6 | c.627C>T p.P209= | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as rs969424209, COSV53044148; called by muse, mutect2
- PCDH11X | c.2496T>G p.A832= | Silent (SNP) | VAF 34/640 reads (5%) | called by muse, mutect2
- PCDH11X | c.2866C>T p.L956= | Silent (SNP) | VAF 29/728 reads (4%) | called by muse, mutect2
- PCDHB5 | c.2226G>T p.G742= | Silent (SNP) | VAF 28/518 reads (5%) | called by muse, mutect2
- POLR2B | c.423G>A p.Q141= | Silent (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- SCN7A | c.1053T>A p.A351= | Silent (SNP) | VAF 38/522 reads (7%) | called by muse, mutect2
- TIMM8B | c.12G>A p.L4= | Silent (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- WASHC4 | c.3219C>T p.F1073= | Silent (SNP) | VAF 16/431 reads (4%) | called by muse, mutect2
- WRNIP1 | c.1179C>T p.I393= | Silent (SNP) | VAF 30/798 reads (4%) | catalogued as rs1261256493, COSV66356207; called by muse, mutect2
- ZNF334 | c.1479A>G p.K493= | Silent (SNP) | VAF 26/430 reads (6%) | catalogued as rs761279103; called by muse, mutect2
- ZNF569 | c.96G>A p.L32= | Silent (SNP) | VAF 15/303 reads (5%) | catalogued as rs1318032715; called by muse, mutect2
- AL353804.7 | chrX:73846660 G>A | 5'Flank (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- AP003548.1 | n.430T>A | RNA (SNP) | VAF 26/451 reads (6%) | catalogued as rs984408072; called by muse, mutect2
- ARHGEF10L | c.3185-17G>T | Intron (SNP) | VAF 16/180 reads (9%) | catalogued as rs530209225; called by muse, mutect2
- C3P1 | n.2484C>A | RNA (SNP) | VAF 36/601 reads (6%) | called by muse, mutect2
- CRIP2 | chr14:105473266 C>T | 5'Flank (SNP) | VAF 38/599 reads (6%) | called by muse, mutect2
- DDX39B | c.-132C>A | 5'UTR (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- FAM90A27P | n.1233C>A | RNA (SNP) | VAF 30/799 reads (4%) | catalogued as rs1269442871; called by muse, mutect2
- GNG5P2 | n.136G>A | RNA (SNP) | VAF 22/588 reads (4%) | called by muse, mutect2
- GOLGA6L2 | c.*153C>T | 3'UTR (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- JPH3 | chr16:87702155 C>A | 3'Flank (SNP) | VAF 32/560 reads (6%) | called by muse, mutect2
- LINC00470 | n.1361-2482T>A | Intron (SNP) | VAF 22/558 reads (4%) | called by muse, mutect2
- MIR124-2HG | n.359G>A | RNA (SNP) | VAF 16/324 reads (5%) | called by muse, mutect2
- PCCB | chr3:136334258 G>A | 3'Flank (SNP) | VAF 20/582 reads (3%) | called by muse, mutect2
- POFUT2 | c.382+9G>T | Intron (SNP) | VAF 27/353 reads (8%) | catalogued as COSV57960142; called by muse, mutect2
- SGPL1 | c.410-20G>A | Intron (SNP) | VAF 32/672 reads (5%) | called by muse, mutect2
- STAT3 | c.1653+44C>A | Intron (SNP) | VAF 17/576 reads (3%) | called by muse, mutect2
- TMEM181 | c.-10G>A | 5'UTR (SNP) | VAF 13/183 reads (7%) | catalogued as rs774487369; called by muse, mutect2
- VPS35 | c.3+52G>T | Intron (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
